Somatic mutation profile of tumor specimen MMRF_1489_1_BM_CD138pos (aliquot MMRF_1489_1_BM_CD138pos_T1_KAS5U_L01924) from MMRF case MMRF_1489, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 72.7 years (26,551 days).
Specimen MMRF_1489_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b49560cf-d75c-498f-9f77-0f41fd42a60e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1489_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1489_1_PB_Whole_C2_KAS5U_L01934; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9f972cc7-1828-4a13-a1a6-3c99e23106d9

The open-access MAF lists 135 somatic variants for this specimen: 64 protein-altering or splice-affecting, 18 silent, 53 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, 3'UTR 28, Silent 18, Intron 15, Nonsense Mutation 4, 5'UTR 4, RNA 3, 3'Flank 3, Frame Shift Ins 2, Splice Region 2, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRV1 | c.9623G>C p.R3208T | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV67983323; called by muse, mutect2
- AL592490.1 | c.1693G>A p.E565K | Missense Mutation (SNP) | VAF 12/134 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as rs559148086, COSV69425665; called by muse, mutect2
- ANK2 | c.8252C>T p.S2751F | Missense Mutation (SNP) | VAF 55/111 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.66); catalogued as COSV52175840; called by muse, mutect2, varscan2
- CAND2 | c.1229C>T p.P410L (on ENST00000456430 / NM_001162499.2; = p.P317L on NM_012298.3) | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs767977141; called by muse, mutect2, varscan2
- CELSR2 | c.2020G>A p.D674N | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV99603666; called by muse, mutect2, varscan2
- DACT2 | c.1859G>A p.R620H | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs771407706; called by muse, mutect2, varscan2
- DBH | c.1648G>A p.D550N | Missense Mutation (SNP) | VAF 86/270 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs529732819; called by muse, mutect2, varscan2
- DQX1 | c.1039C>T p.R347* | Nonsense Mutation (SNP) | VAF 57/169 reads (34%) | catalogued as rs774452490, COSV66352977, COSV66353194; called by muse, mutect2, varscan2
- FUT4 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); catalogued as rs1168413773; called by muse, mutect2, varscan2
- IGHV2-70D | c.235T>C p.F79L | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1457244699; called by muse, varscan2
- KDM3B | c.722C>G p.S241W | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV100069495; called by muse, mutect2, varscan2
- MACROH2A2 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as rs375442516; called by muse, mutect2, varscan2
- MYH6 | c.2173C>T p.R725C | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.994); catalogued as rs748667312, COSV100676861; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYT1L | c.1144C>T p.L382F | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV67721601; called by muse, mutect2, varscan2
- PNKD | c.964C>T p.R322W | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751050132; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PPP1R15A | c.271G>T p.E91* | Nonsense Mutation (SNP) | VAF 15/120 reads (13%) | catalogued as rs1271154078; called by muse, mutect2, varscan2
- PRDM1 | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64848271; called by muse, mutect2, varscan2
- PTPRS | c.1291C>T p.R431W | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1237664443, COSV53621524; called by muse, mutect2, varscan2
- RBM26 | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1167805039; called by muse, mutect2, varscan2
- RYR3 | c.6685G>A p.G2229S | Missense Mutation (SNP) | VAF 78/131 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763545124, COSV100774382; called by muse, mutect2, varscan2
- TLE2 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 121/182 reads (66%) | SIFT tolerated (0.07); PolyPhen benign (0.077); catalogued as rs1018382206, COSV53579712; called by muse, mutect2, varscan2
- TMEM115 | c.88G>C p.V30L | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.021); catalogued as COSV51704933; called by muse, mutect2, varscan2
- ZNF462 | c.6062G>A p.R2021H | Missense Mutation (SNP) | VAF 53/226 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as rs762238596; called by muse, mutect2, varscan2
- ACTB | c.985-1G>C p.X329_splice | Splice Site (SNP) | VAF 28/83 reads (34%) | called by muse, mutect2, varscan2
- AMIGO2 | c.31C>G p.L11V | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP28 | c.800A>T p.N267I (on ENST00000383472 / NM_001366230.1; = p.N108I on NM_001010000.3) | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- BBOX1 | c.584C>A p.T195K | Missense Mutation (SNP) | VAF 103/385 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- BMP6 | c.1345C>G p.L449V | Missense Mutation (SNP) | VAF 62/183 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CATSPERE | c.2776T>A p.Y926N | Missense Mutation (SNP) | VAF 73/153 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDC20 | c.455A>G p.Y152C | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.591); called by muse, mutect2
- COPB1 | c.1286A>C p.Q429P | Missense Mutation (SNP) | VAF 123/176 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- DLGAP4 | c.1238G>A p.R413H | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- DOCK5 | c.560A>G p.H187R | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DPYSL5 | c.1076G>T p.W359L | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- DUT | c.281-8C>G | Splice Region (SNP) | VAF 33/80 reads (41%) | called by muse, mutect2, varscan2
- FAM13B | c.2095-6T>G | Splice Region (SNP) | VAF 46/84 reads (55%) | called by muse, mutect2, varscan2
- FRMPD2 | c.822G>C p.Q274H | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRIK1 | c.2679A>C p.L893F | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRIK4 | c.1242C>A p.F414L | Missense Mutation (SNP) | VAF 95/280 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- IRX4 | c.577T>C p.F193L | Missense Mutation (SNP) | VAF 40/164 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- KALRN | c.7546A>T p.N2516Y (on ENST00000360013 / NM_001024660.4; = p.N819Y on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- KDM4C | c.538T>C p.F180L | Missense Mutation (SNP) | VAF 148/286 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- KRT5 | c.322G>T p.G108C | Missense Mutation (SNP) | VAF 94/164 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.116); called by muse, mutect2
- LMO7 | c.1073T>G p.V358G (on ENST00000357063; = p.V88G on NM_015842.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/125 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- LRP1B | c.10318T>A p.Y3440N | Missense Mutation (SNP) | VAF 54/115 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- LSAMP | c.283A>G p.S95G | Missense Mutation (SNP) | VAF 62/192 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MRGPRX2 | c.169T>G p.F57V | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- NPR3 | c.1302T>A p.D434E | Missense Mutation (SNP) | VAF 52/238 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- PINLYP | c.265A>G p.M89V | Missense Mutation (SNP) | VAF 79/109 reads (72%) | SIFT tolerated (0.41); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- POLR1C | c.154G>T p.D52Y | Missense Mutation (SNP) | VAF 298/451 reads (66%) | SIFT deleterious (0.02); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- POP5 | c.14A>G p.K5R | Missense Mutation (SNP) | VAF 68/139 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RYR2 | c.5828G>A p.R1943Q | Missense Mutation (SNP) | VAF 59/148 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SCN9A | c.88A>T p.R30* | Nonsense Mutation (SNP) | VAF 97/209 reads (46%) | called by muse, mutect2, varscan2
- SPECC1L | c.2148T>A p.N716K | Missense Mutation (SNP) | VAF 50/97 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- STAR | c.60G>A p.M20I | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TENT5C | c.166_172del p.R56Gfs*14 | Frame Shift Del (DEL) | VAF 11/123 reads (9%) | called by mutect2, pindel
- TENT5C | c.620dup p.H207Qfs*14 | Frame Shift Ins (INS) | VAF 12/124 reads (10%) | called by mutect2, pindel
- THBD | c.230G>T p.G77V | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.618); called by muse, mutect2, varscan2
- TMEM232 | c.220dup p.I74Nfs*6 | Frame Shift Ins (INS) | VAF 14/68 reads (21%) | called by mutect2, pindel, varscan2
- TMIE | c.7G>A p.G3R | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TOX3 | c.797T>C p.F266S | Missense Mutation (SNP) | VAF 60/105 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- USP36 | c.3079C>T p.Q1027* | Nonsense Mutation (SNP) | VAF 15/163 reads (9%) | called by muse, mutect2
- ZNF234 | c.1532C>T p.P511L | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- ZNF286A | c.773T>A p.L258H | Missense Mutation (SNP) | VAF 60/176 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ADCYAP1 | c.204G>A p.P68= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV52487153; called by muse, mutect2, varscan2
- ARHGEF10 | c.1267A>C p.R423= (on ENST00000398564; = p.R398= on NM_014629.4) | Silent (SNP) | VAF 20/52 reads (38%) | called by muse, mutect2, varscan2
- BMP10 | c.771T>C p.S257= | Silent (SNP) | VAF 27/119 reads (23%) | called by muse, mutect2, varscan2
- CYB561 | c.295C>T p.L99= | Silent (SNP) | VAF 26/90 reads (29%) | catalogued as COSV62539716; called by muse, mutect2, varscan2
- ETV6 | c.810C>G p.P270= | Silent (SNP) | VAF 56/109 reads (51%) | called by muse, mutect2, varscan2
- FCGBP | c.5958C>A p.G1986= | Silent (SNP) | VAF 6/33 reads (18%) | catalogued as COSV55446366; called by muse, mutect2, varscan2
- IGLV3-1 | c.72T>A p.T24= | Silent (SNP) | VAF 40/87 reads (46%) | called by muse, mutect2, varscan2
- MTMR4 | c.1686C>A p.A562= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV100051061; called by muse, mutect2, varscan2
- MXRA8 | c.1284G>A p.K428= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as rs764484988; called by muse, mutect2, varscan2
- PGAP6 | c.1827C>T p.C609= | Silent (SNP) | VAF 30/62 reads (48%) | catalogued as rs374864682; called by muse, mutect2, varscan2
- PIF1 | c.789C>A p.I263= | Silent (SNP) | VAF 126/220 reads (57%) | catalogued as COSV51424917; called by muse, varscan2
- PTPRD | c.267T>C p.T89= | Silent (SNP) | VAF 73/136 reads (54%) | called by muse, mutect2, varscan2
- SORCS3 | c.2379T>C p.Y793= | Silent (SNP) | VAF 63/135 reads (47%) | called by muse, mutect2, varscan2
- SOWAHC | c.1161C>T p.A387= | Silent (SNP) | VAF 50/107 reads (47%) | called by muse, mutect2, varscan2
- STX1B | c.603C>A p.I201= | Silent (SNP) | VAF 83/159 reads (52%) | called by muse, mutect2, varscan2
- TAS2R9 | c.60G>T p.G20= | Silent (SNP) | VAF 49/122 reads (40%) | called by muse, mutect2, varscan2
- WWC1 | c.408G>A p.E136= | Silent (SNP) | VAF 36/72 reads (50%) | called by muse, mutect2, varscan2
- ZFPM1 | c.1545C>T p.P515= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as rs753798461, COSV60321274; called by muse, mutect2, varscan2
- ABHD2 | c.*1039A>G | 3'UTR (SNP) | VAF 5/80 reads (6%) | called by muse, mutect2
- ABTB2 | c.-251G>A | 5'UTR (SNP) | VAF 19/86 reads (22%) | catalogued as rs1310363134; called by muse, mutect2, varscan2
- ADAM22 | c.2576+2356C>T | Intron (SNP) | VAF 4/86 reads (5%) | called by muse, mutect2
- ADGRL2 | c.1782+113A>G | Intron (SNP) | VAF 6/10 reads (60%) | called by muse, mutect2, varscan2
- ATP7B | c.*1345C>A | 3'UTR (SNP) | VAF 9/30 reads (30%) | called by muse, mutect2, varscan2
- C19orf12 | chr19:29701129 G>A | 3'Flank (SNP) | VAF 27/63 reads (43%) | catalogued as rs112544662; called by muse, mutect2, varscan2
- C5orf64 | n.513-43146A>C | Intron (SNP) | VAF 7/63 reads (11%) | called by muse, mutect2, varscan2
- CA12 | c.*1647T>C | 3'UTR (SNP) | VAF 6/134 reads (4%) | called by muse, mutect2
- CADM2 | chr3:86067578 A>T | 3'Flank (SNP) | VAF 8/106 reads (8%) | called by muse, mutect2
- CD274 | c.*1830C>T | 3'UTR (SNP) | VAF 15/63 reads (24%) | called by muse, mutect2, varscan2
- CDH8 | c.*185G>C | 3'UTR (SNP) | VAF 20/50 reads (40%) | called by muse, mutect2, varscan2
- CNOT2 | c.*202A>T | 3'UTR (SNP) | VAF 22/44 reads (50%) | called by muse, mutect2, varscan2
- COPRS | c.99+257_99+261del | Intron (DEL) | VAF 30/86 reads (35%) | called by mutect2, pindel, varscan2
- CRISPLD1 | c.*215C>T | 3'UTR (SNP) | VAF 14/37 reads (38%) | called by muse, mutect2, varscan2
- CSNK1A1L | c.-122C>T | 5'UTR (SNP) | VAF 49/85 reads (58%) | called by muse, mutect2, varscan2
- CUL2 | c.*920C>T | 3'UTR (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- DEPDC1 | c.*483A>T | 3'UTR (SNP) | VAF 30/239 reads (13%) | called by muse, mutect2, varscan2
- DEUP1 | c.297+161T>C | Intron (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2
- DIAPH2 | c.*385G>T | 3'UTR (SNP) | VAF 53/55 reads (96%) | called by muse, mutect2, varscan2
- EPC2 | c.*658T>A | 3'UTR (SNP) | VAF 41/78 reads (53%) | called by muse, mutect2, varscan2
- FN1 | c.6442-71G>A | Intron (SNP) | VAF 13/40 reads (33%) | called by muse, mutect2
- GPR55 | c.-77G>C | 5'UTR (SNP) | VAF 63/132 reads (48%) | called by muse, mutect2, varscan2
- HAPLN1 | c.*2189A>T | 3'UTR (SNP) | VAF 17/99 reads (17%) | catalogued as rs893643327; called by muse, mutect2, varscan2
- HYDIN2 | n.7094C>T | RNA (SNP) | VAF 21/60 reads (35%) | catalogued as rs1196772153; called by muse, mutect2, varscan2
- IL17RA | c.*2764C>T | 3'UTR (SNP) | VAF 29/72 reads (40%) | called by muse, mutect2, varscan2
- IMPA1 | c.*620T>C | 3'UTR (SNP) | VAF 13/32 reads (41%) | called by muse, mutect2, varscan2
- IPO11 | c.-7+6047A>T | Intron (SNP) | VAF 59/388 reads (15%) | called by muse, mutect2, varscan2
- KCNMB4 | c.*1149A>C | 3'UTR (SNP) | VAF 20/65 reads (31%) | called by muse, mutect2, varscan2
- LGI1 | c.-184C>T | 5'UTR (SNP) | VAF 35/62 reads (56%) | called by muse, mutect2, varscan2
- LINC01600 | n.1271C>T | RNA (SNP) | VAF 10/36 reads (28%) | catalogued as rs1005995764; called by mutect2, varscan2
- MALT1 | c.*4460_*4461del | 3'UTR (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- MARK4 | c.253-27G>A | Intron (SNP) | VAF 42/202 reads (21%) | catalogued as rs775522696; called by muse, mutect2, varscan2
- METTL21A | chr2:207612416 T>A | 3'Flank (SNP) | VAF 4/11 reads (36%) | called by muse, mutect2, varscan2
- MFN2 | c.*1732A>G | 3'UTR (SNP) | VAF 61/104 reads (59%) | called by muse, mutect2, varscan2
- MSRA | c.331+5481G>C | Intron (SNP) | VAF 38/90 reads (42%) | called by muse, mutect2, varscan2
- MST1L | n.3121T>G | RNA (SNP) | VAF 162/1133 reads (14%) | called by muse, mutect2, varscan2
- NIM1K | c.*105T>A | 3'UTR (SNP) | VAF 201/414 reads (49%) | called by muse, mutect2, varscan2
- OSMR | c.1585+469G>T | Intron (SNP) | VAF 9/67 reads (13%) | called by muse, mutect2, varscan2
- PAXIP1 | c.*51T>G | 3'UTR (SNP) | VAF 14/182 reads (8%) | catalogued as rs575998054; called by muse, mutect2
- PELO | c.*616_*617insA | 3'UTR (INS) | VAF 31/185 reads (17%) | called by mutect2, pindel, varscan2
- PLEKHO1 | c.423+21dup | Intron (INS) | VAF 41/122 reads (34%) | called by mutect2, pindel, varscan2
- PPARGC1A | c.*354A>C | 3'UTR (SNP) | VAF 24/41 reads (59%) | called by muse, mutect2, varscan2
- PTAR1 | c.86+2072G>A | Intron (SNP) | VAF 20/179 reads (11%) | called by muse, mutect2, varscan2
- RAB11FIP4 | c.*395A>G | 3'UTR (SNP) | VAF 5/87 reads (6%) | called by muse, mutect2
- RYBP | c.*3266G>A | 3'UTR (SNP) | VAF 34/109 reads (31%) | called by muse, mutect2, varscan2
- RYBP | c.*1461A>T | 3'UTR (SNP) | VAF 11/108 reads (10%) | catalogued as rs1263163370, COSV72180313; called by muse, varscan2
- SERPINA3 | c.644-582C>T | Intron (SNP) | VAF 90/203 reads (44%) | catalogued as rs1458327554; called by muse, mutect2, varscan2
- SLC2A3 | c.*1492T>G | 3'UTR (SNP) | VAF 40/488 reads (8%) | called by muse, mutect2
- SPAG9 | c.*2121T>C | 3'UTR (SNP) | VAF 40/102 reads (39%) | called by mutect2, varscan2
- THBS4 | c.1194+51C>A | Intron (SNP) | VAF 22/113 reads (19%) | catalogued as rs760123579; called by muse, mutect2, varscan2
- TM4SF1 | c.*475A>G | 3'UTR (SNP) | VAF 42/142 reads (30%) | called by muse, mutect2, varscan2
- UBAP2 | c.2176-800T>C | Intron (SNP) | VAF 53/119 reads (45%) | called by muse, mutect2, varscan2
- UQCR10 | c.*83A>G | 3'UTR (SNP) | VAF 83/214 reads (39%) | catalogued as rs774177914; called by muse, mutect2, varscan2
